Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012424-03A.2 (aliquot TARGET-15-SJMPAL012424-03A.2-01D) from TARGET case TARGET-15-SJMPAL012424, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,050 days).
Specimen TARGET-15-SJMPAL012424-03A.2: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 236dac8e-de56-4c51-94e4-a9cca71f9f30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012424-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012424-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cad45ba-7d1a-42d6-8b9b-97dbc5d7750d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SVEP1 | c.3196C>T p.L1066F | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1409338019; called by muse, mutect2, varscan2
- AKAP11 | c.4915C>A p.Q1639K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- GRIA4 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- NVL | c.1180+1G>T p.X394_splice | Splice Site (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- ZNF486 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RBM4 | c.156A>C p.I52= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- RIT2 | c.486C>T p.T162= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV100449498; called by muse, mutect2, varscan2
- PDE10A | c.106+91775G>A | Intron (SNP) | VAF 49/93 reads (53%) | catalogued as rs570360405; called by muse, mutect2, varscan2
- PDLIM3 | c.94-533C>T | Intron (SNP) | VAF 4/11 reads (36%) | catalogued as rs1485688639; called by mutect2, varscan2
